Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5304, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5304-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Brain tumor - right frontal.

Gross Examination:

A. "Brain tumor frozen/permanent monoclonal antibodies", received fresh for frozen section. A 1.8 x 1.7 x 0.5 cm fragment of soft tan tissue is received for frozen section. The frozen section remnant is submitted in toto in A1. A portion of the remainder is retained in formalin and the remainder of the specimen is submitted in toto in A2.

B. "Brain tumor", received fresh and placed in formalin. A 7.0 x 3.9 x 2.3 cm aggregate of one large fragment and multiple smaller fragments of firm pink-tan tissue is received. The larger fragment has areas suggestive of differentiation between gray and white matter that progressively deteriorate. There is a 2.0 x 1.8 x 1.2 cm softened area on the periphery of the larger fragment. Representative of smaller fragment is submitted in B1, and representative of larger fragment in B2 through B6.

Intraoperative Consultation:

A. "Brain tumor frozen/permanent monoclonal antibodies": AF1 - glioma, high grade

Microscopic Examination:

The tissue is brain which exhibits an infiltrate of malignant glial cells exhibiting hyperchromatic mildly pleomorphic nuclei. The overall cellularity is quite dense. Occasional mitoses are encountered. Individual and necrotic tumor cells are readily found. There is no evidence of necrosis. Infiltration of the cortex is noted with focal subarachnoid accumulation present.

Immunohistochemical Findings:

Immunohistochemical stains for 81C6 reveal moderate multifocal perivascular immunoreactivity.

Immunohistochemical stains for Mel-14 reveal moderate diffuse perivascular reactivity.

No immunoreactivity was noted in the negative control antibodies M45 or RPC5.

Continued on next page...

[page 2 of 2]
Immunohistochemical Findings:

DIAGNOSIS:

A. "BRAIN TUMOR":

ANAPLASTIC (ASTROCYTOMA (WHO GRADE III)).

B. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

** END OF REPORT **

Page: 2

FILE COPY

Patient:
HX No:
Location:

Source: NCI Genomic Data Commons file e387f024-0eb9-462b-8bce-12d293229516 (TCGA-E1-5304.4180DEB2-569A-49D5-9B0C-769FB2451409.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).